Somatic mutation profile of tumor specimen 0DAWAM from CCDI case PBBJNH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,173 days).
Specimen 0DAWAM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 738dd5d2-5aab-427c-9a66-0521e9c9e994.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAWAA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da5b2503-57b6-4cdc-9c67-0930c8d2fb15

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Intron 3, 3'UTR 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT2 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 84/1894 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV55924872; called by muse, mutect2
- C9orf72 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 137/2127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs575487786; called by muse, mutect2
- HDGFL1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.082); catalogued as rs747803483; called by muse, mutect2, varscan2
- KANSL2 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 429/1209 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as COSV100771035; called by muse, mutect2, varscan2
- KRT79 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 147/1531 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs199955846, COSV57940423; called by muse, mutect2, varscan2
- LSAMP | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 429/869 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs374906199; called by muse, mutect2, varscan2
- MATN3 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 36/1261 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1262271401; called by muse, mutect2
- RPUSD1 | c.410-1G>A p.X137_splice | Splice Site (SNP) | VAF 180/429 reads (42%) | catalogued as COSV50099711; called by muse, mutect2, varscan2
- SLC1A2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 141/2174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145275821; called by muse, mutect2
- SLU7 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 743/1776 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51790394; called by muse, mutect2, varscan2
- ZHX2 | c.1549C>T p.R517* | Nonsense Mutation (SNP) | VAF 140/1906 reads (7%) | catalogued as rs759681757, COSV100072658; called by muse, mutect2
- APC | c.571T>C p.Y191H | Missense Mutation (SNP) | VAF 58/2196 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- BAG5 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 28/768 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); called by muse, mutect2
- CNOT6 | c.857T>G p.F286C | Missense Mutation (SNP) | VAF 54/1844 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COX15 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 95/871 reads (11%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- DBNL | c.1135C>G p.L379V (on ENST00000448521 / NM_001014436.3; = p.L380V on NM_014063.7) | Missense Mutation (SNP) | VAF 803/1858 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DCAF12L2 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 207/231 reads (90%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DLGAP1 | c.2531A>G p.Q844R | Missense Mutation (SNP) | VAF 204/1727 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GOSR1 | c.440+5G>C | Splice Region (SNP) | VAF 104/1611 reads (6%) | called by muse, mutect2
- MOK | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 101/1239 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); called by muse, mutect2
- MYO7A | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 94/1482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PID1 | c.190C>G p.P64A (on ENST00000354069 / NM_001330156.1; = p.P62A on NM_017933.5) | Missense Mutation (SNP) | VAF 800/1595 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SORBS1 | c.2983del p.V995Sfs*9 | Frame Shift Del (DEL) | VAF 48/414 reads (12%) | called by mutect2, varscan2
- TG | c.2113T>A p.C705S | Missense Mutation (SNP) | VAF 1356/2466 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK6 | c.2115C>T p.G705= | Silent (SNP) | VAF 176/1179 reads (15%) | catalogued as rs760502578, COSV99370975; called by muse, mutect2, varscan2
- GP5 | c.1413G>A p.E471= | Silent (SNP) | VAF 50/421 reads (12%) | catalogued as rs1256759797; called by muse, mutect2, varscan2
- MYO15A | c.4659C>T p.D1553= | Silent (SNP) | VAF 28/772 reads (4%) | catalogued as rs1016430407; called by muse, mutect2
- OR3A3 | c.312C>T p.D104= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs567381667, COSV99351591; called by mutect2, varscan2
- TLNRD1 | c.777C>T p.S259= | Silent (SNP) | VAF 24/342 reads (7%) | catalogued as rs768191148; called by muse, mutect2
- DDX60 | c.4270-45T>A | Intron (SNP) | VAF 10/318 reads (3%) | called by muse, mutect2
- DOCK6 | c.1832+41G>T | Intron (SNP) | VAF 29/481 reads (6%) | called by muse, mutect2
- LY9 | c.454+1743G>A | Intron (SNP) | VAF 116/1554 reads (7%) | catalogued as rs767829480, COSV54434321; called by muse, mutect2
- MGRN1 | c.*2625G>A | 3'UTR (SNP) | VAF 56/648 reads (9%) | called by muse, mutect2
- RASA3 | c.*7C>T | 3'UTR (SNP) | VAF 403/1112 reads (36%) | catalogued as rs763846693, COSV100480958; called by muse, mutect2, varscan2
